Somatic mutation profile of tumor specimen C3L-00980-02 (aliquot CPT0122660009) from CPTAC case C3L-00980, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 63.3 years (23,135 days).
Specimen C3L-00980-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44c52ab3-ebef-4a30-af15-2a8224b682ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00980-31 (Blood Derived Normal), aliquot CPT0124660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0444b05e-cf6e-4aae-8f23-2169589d20c1

The open-access MAF lists 73 somatic variants for this specimen: 48 protein-altering or splice-affecting, 19 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, Intron 4, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.341-2A>G p.X114_splice | Splice Site (SNP) | VAF 29/210 reads (14%) | hotspot (GDC flag); catalogued as rs869025637, CS071275, COSV56542830, COSV56544966, COSV56548666, COSV56554645; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCLRE1A | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs764568699; called by muse, mutect2
- DDX59 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 12/99 reads (12%) | catalogued as COSV100494711, COSV58752386; called by muse, mutect2, varscan2
- HSPA12B | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.075); catalogued as COSV54768902; called by muse, mutect2, varscan2
- IQCA1 | c.1889C>A p.P630H | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54501460; called by muse, mutect2, varscan2
- MYH13 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs202246911; called by muse, mutect2
- MYH7 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as CM1414575, COSV62516149; called by muse, mutect2
- NBPF1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1480477431; called by muse, mutect2, varscan2
- NDUFA9 | c.135A>C p.K45N | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99865317; called by muse, mutect2, varscan2
- OR5AR1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.145); catalogued as rs747498545; called by muse, mutect2, varscan2
- SCNN1G | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 24/359 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.433); catalogued as rs528336880, COSV55597639; called by muse, mutect2
- SETD2 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 22/160 reads (14%) | catalogued as rs1278528667, COSV57432605; called by muse, mutect2, varscan2
- SLC25A30 | c.257A>T p.K86M | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60434047; called by muse, mutect2, varscan2
- SLC7A3 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs752706379; called by muse, mutect2, varscan2
- VPS13B | c.11711C>G p.T3904R | Missense Mutation (SNP) | VAF 23/452 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV62135436; called by muse, mutect2
- WASF1 | c.89C>G p.T30S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV55619538; called by muse, mutect2
- ZNF280C | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV63969472; called by muse, varscan2
- ZNF536 | c.479G>A p.C160Y | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62831044; called by muse, varscan2
- ADAMTS20 | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ANXA13 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARL16 | c.306+1G>T p.X102_splice | Splice Site (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2
- ASB17 | c.864A>T p.Q288H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- BIVM-ERCC5 | c.3557A>G p.N1186S | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.01); called by muse, mutect2
- CATSPER2 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDK10 | c.859C>T p.H287Y (on ENST00000353379 / NM_052988.5; = p.H216Y on NM_052987.4) | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- CPEB4 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- EIF4E2 | c.135+1G>A p.X45_splice | Splice Site (SNP) | VAF 21/102 reads (21%) | called by muse, varscan2
- ELL | c.1721T>G p.I574S | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FN1 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FRS3 | c.999A>T p.E333D | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- GK2 | c.1283T>C p.M428T | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- GTF2IRD1 | c.2515G>T p.E839* (on ENST00000265755 / NM_016328.3; = p.E824* on NM_005685.4) | Nonsense Mutation (SNP) | VAF 17/175 reads (10%) | called by muse, mutect2, varscan2
- IGLV1-40 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- KLHL41 | c.576del p.E193Kfs*8 | Frame Shift Del (DEL) | VAF 13/112 reads (12%) | called by mutect2, varscan2
- MYOM1 | c.4648G>A p.A1550T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2
- N4BP1 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.549); called by muse, mutect2
- NAV3 | c.1550A>C p.K517T | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NUP153 | c.1230A>C p.K410N | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2
- PHLPP1 | c.5110T>C p.Y1704H | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.187); called by muse, mutect2
- PLXNA2 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PPP1R32 | c.122T>C p.F41S | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC18A3 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNRPN | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, varscan2
- SUSD1 | c.1946C>G p.A649G | Missense Mutation (SNP) | VAF 27/387 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2
- TRIM33 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR49 | c.525G>A p.W175* (on ENST00000308378 / NM_001366158.1; = p.W516* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/215 reads (14%) | called by muse, mutect2, varscan2
- ZFYVE16 | c.1727A>C p.N576T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZMIZ2 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- AMHR2 | c.1131C>T p.A377= | Silent (SNP) | VAF 12/220 reads (5%) | catalogued as rs748279145, COSV57685497; called by muse, mutect2
- CCDC27 | c.795G>A p.L265= | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as COSV53902503; called by muse, mutect2, varscan2
- CD2BP2 | c.624G>A p.Q208= | Silent (SNP) | VAF 54/346 reads (16%) | called by muse, mutect2, varscan2
- CHD3 | c.5631G>A p.A1877= (on ENST00000330494 / NM_001005273.3; = p.A1843= on NM_005852.4) | Silent (SNP) | VAF 58/451 reads (13%) | catalogued as rs369541480; called by muse, mutect2, varscan2
- CPT1A | c.1131G>A p.E377= | Silent (SNP) | VAF 42/276 reads (15%) | catalogued as rs1215645933, COSV55759035; called by muse, mutect2, varscan2
- CUX1 | c.3021C>T p.N1007= | Silent (SNP) | VAF 9/177 reads (5%) | catalogued as rs139470121; called by muse, mutect2
- FAU | c.201A>G p.V67= | Silent (SNP) | VAF 24/194 reads (12%) | called by muse, mutect2, varscan2
- FNDC7 | c.2037T>C p.C679= | Silent (SNP) | VAF 33/274 reads (12%) | called by muse, mutect2, varscan2
- HNF1B | c.930G>T p.R310= | Silent (SNP) | VAF 14/217 reads (6%) | called by muse, mutect2
- HSPG2 | c.2595C>T p.P865= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as rs758700941, COSV65975364; called by muse, mutect2
- NOD2 | c.3036C>A p.T1012= | Silent (SNP) | VAF 31/348 reads (9%) | catalogued as rs762502185; called by muse, mutect2
- OR56A1 | c.255G>T p.L85= | Silent (SNP) | VAF 25/209 reads (12%) | called by muse, mutect2, varscan2
- PITRM1 | c.178C>T p.L60= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as rs757911747; called by muse, mutect2, varscan2
- PPP1R10 | c.492A>C p.G164= | Silent (SNP) | VAF 22/185 reads (12%) | called by muse, mutect2, varscan2
- PPP2R2D | c.573A>G p.V191= | Silent (SNP) | VAF 12/161 reads (7%) | called by muse, mutect2
- RHOC | c.444G>A p.A148= | Silent (SNP) | VAF 15/244 reads (6%) | catalogued as rs371111746; called by muse, mutect2
- SLC12A2 | c.1434G>A p.G478= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- SLC12A7 | c.2961C>T p.I987= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as rs139553130, COSV53755202; called by muse, mutect2, varscan2
- TNFSF10 | c.414T>G p.S138= | Silent (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2, varscan2
- FAM21FP | n.192G>C | RNA (SNP) | VAF 23/291 reads (8%) | called by muse, mutect2
- L2HGDH | chr14:50237711 C>G | 3'Flank (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- MACF1 | c.543+11114G>C | Intron (SNP) | VAF 30/207 reads (14%) | called by muse, mutect2, varscan2
- MS4A15 | c.405+206del | Intron (DEL) | VAF 28/206 reads (14%) | called by mutect2, pindel, varscan2
- TRMO | c.409+474T>A | Intron (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- TWF1 | c.103+251T>G | Intron (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
